Gene-level copy-number profile of tumor specimen TARGET-10-PATZYC-09A from TARGET case TARGET-10-PATZYC, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.7 years (1,350 days).
Specimen TARGET-10-PATZYC-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-ALL-P2.7c40dc68-3fc6-5703-ac2f-2056f5eed406.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-10-PATZYC-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 393 have no estimate.
https://portal.gdc.cancer.gov/files/462d489e-564f-4f22-821a-09d43976554c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 63; copy number 1: 3,964; copy number 2: 53,714; copy number 3: 2,248; copy number 4: 240; copy number 5: 1.

Homozygous deletions (total copy number 0; autosomes only): 62 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:38,239,580–38,329,643, 14 genes: TRGC2, TRGJ2, TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2.
- chr9:21,802,636–22,029,594, 2 genes (within-gene range 0–1): MTAP, AL359922.1.
- chr9:21,858,910–22,214,672, 12 genes (within-gene range 0–1): AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1.
- chr11:5,776,165–5,783,355, 1 gene: OR52N5.
- chr11:96,447,132–96,514,748, 3 genes (within-gene range 0–2): JRKL-AS1, RNA5SP346, LINC02737.
- chr14:22,096,032–22,482,959, 30 genes (within-gene range 0–2): TRDV1, TRAV24, TRAV25, TRAV26-1, TRAV8-7, TRAV27, TRAV28, TRAV29DV5, TRAV30, TRAV31, TRAV32, TRAV33, AC244502.1, TRAV26-2, TRAV34, TRAV35, TRAV36DV7, TRAV37, TRAV38-1, TRAV38-2DV8, TRAV39, TRAV40, TRAV41, AC244502.2, AC244502.3, TRDV2, TRDD1, TRDD2, TRDD3, TRDJ1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:54,864,674–54,869,122, 1 gene, copy number 5: AC051618.1.

Autosomal genes at a single copy (total copy number 1): 1,576. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
